Somatic mutation profile of tumor specimen TCGA-EJ-8468-01A (aliquot TCGA-EJ-8468-01A-21D-2395-08) from TCGA case TCGA-EJ-8468, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.0 years (23,371 days).
Specimen TCGA-EJ-8468-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce3ff8d5-39b4-408f-866b-d5b2224e889a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-8468-10A (Blood Derived Normal), aliquot TCGA-EJ-8468-10A-01D-2395-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77445403-4f27-4b40-9daa-62e11c7b8e02

The open-access MAF lists 28 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, 3'Flank 1, Frame Shift Ins 1, RNA 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.398T>C p.F133S | Missense Mutation (SNP) | VAF 47/147 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519967, COSV61653174, COSV61653874; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADGRE2 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); catalogued as rs563655526, COSV59693676; called by muse, mutect2, varscan2
- CSMD3 | c.8558C>T p.S2853L (on ENST00000297405 / NM_001363185.1; = p.S2684L on NM_052900.3) | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52187658; called by muse, mutect2, varscan2
- GBP4 | c.1680T>A p.H560Q | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV63254451; called by muse, varscan2
- HMCN1 | c.15532G>A p.G5178R | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.277); catalogued as rs1310129061, COSV54902243; called by muse, mutect2, varscan2
- HOXC4 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200111255, COSV57699043; called by muse, mutect2, varscan2
- LINGO2 | c.1693G>A p.V565M | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV58059919, COSV58064915; called by muse, mutect2
- MAP1A | c.7476C>A p.C2492* | Nonsense Mutation (SNP) | VAF 24/92 reads (26%) | catalogued as COSV55809149; called by muse, mutect2, varscan2
- MYO9B | c.4551C>A p.F1517L | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV68279284, COSV68283106; called by muse, mutect2, varscan2
- RBPMS2 | c.267+1G>A p.X89_splice | Splice Site (SNP) | VAF 23/103 reads (22%) | catalogued as COSV55604568; called by muse, mutect2
- TRPC3 | c.2347G>T p.V783F (on ENST00000379645 / NM_001366479.2; = p.V710F on NM_003305.2) | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV53375950; called by muse, mutect2, varscan2
- VARS2 | c.852A>T p.R284S | Missense Mutation (SNP) | VAF 49/149 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV52559023; called by muse, mutect2, varscan2
- ZC3H4 | c.2536G>T p.D846Y | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1477748474, COSV53413108; called by muse, mutect2, varscan2
- ZFPM1 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV60322392; called by muse, mutect2, varscan2
- ZNF208 | c.2109C>G p.N703K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0.049); catalogued as COSV101237174, COSV68106390; called by muse, mutect2, varscan2
- ZNF799 | c.1819A>G p.K607E | Missense Mutation (SNP) | VAF 38/158 reads (24%) | SIFT tolerated (1); PolyPhen possibly damaging (0.785); catalogued as COSV70122629; called by muse, varscan2
- CHD1 | c.4091_4092dup p.E1365Mfs*7 | Frame Shift Ins (INS) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- DAPP1 | c.651A>T p.Q217H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.788); called by muse, mutect2
- SRRM1 | c.601C>T p.P201S | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.992); called by muse, mutect2
- ACSBG1 | c.1479G>C p.L493= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as COSV51906400; called by muse, mutect2
- ALPI | c.1341G>A p.S447= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV55014710; called by muse, mutect2, varscan2
- APPBP2 | c.1392T>C p.G464= | Silent (SNP) | VAF 4/72 reads (6%) | catalogued as COSV50026768; called by muse, mutect2
- FOXA1 | c.366C>T p.A122= | Silent (SNP) | VAF 7/16 reads (44%) | catalogued as COSV51646042; called by muse, mutect2, varscan2
- MTMR3 | c.2703G>A p.R901= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV60304619; called by muse, mutect2, varscan2
- TANC2 | c.1944C>A p.T648= | Silent (SNP) | VAF 34/149 reads (23%) | catalogued as COSV67334641; called by muse, mutect2, varscan2
- ZNF559 | c.1110A>G p.V370= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV57835672; called by muse, mutect2
- ALMS1P1 | chr2:73701227 C>T | 3'Flank (SNP) | VAF 21/87 reads (24%) | catalogued as rs368579102; called by muse, mutect2, varscan2
- OFCC1 | n.331T>C | RNA (SNP) | VAF 24/103 reads (23%) | catalogued as rs761732835; called by muse, mutect2, varscan2
